Somatic mutation profile of tumor specimen TCGA-ZP-A9D2-01A (aliquot TCGA-ZP-A9D2-01A-11D-A382-10) from TCGA case TCGA-ZP-A9D2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 51.2 years (18,717 days).
Specimen TCGA-ZP-A9D2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbd7d3b8-7b48-4d62-a2b8-28251418eb75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9D2-10B (Blood Derived Normal), aliquot TCGA-ZP-A9D2-10B-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66b32da1-ed54-4d8f-a4d3-f37d014dcf63

The open-access MAF lists 58 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 9, Nonsense Mutation 6, Frame Shift Del 2, Translation Start Site 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AC006059.2 | c.2207G>T p.G736V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100045810; called by muse, mutect2, varscan2
- ANKRD11 | c.4375A>G p.K1459E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.564); catalogued as COSV99970237; called by muse, mutect2, varscan2
- ASCC3 | c.4705C>T p.R1569C | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs756345826, COSV100976801; called by muse, mutect2, varscan2
- BAZ2A | c.5051A>G p.K1684R | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); catalogued as COSV99467277; called by muse, mutect2, varscan2
- CEP95 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV73608569; called by muse, mutect2, varscan2
- COG8 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV54741597; called by muse, mutect2, varscan2
- CP | c.1020T>G p.N340K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99224348; called by muse, mutect2, varscan2
- CSMD3 | c.3734C>G p.A1245G (on ENST00000297405 / NM_001363185.1; = p.A1141G on NM_052900.3) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV52269281, COSV99842985; called by muse, mutect2, varscan2
- DCAF6 | c.286A>G p.N96D | Missense Mutation (SNP) | VAF 288/564 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100394642; called by muse, mutect2, varscan2
- DSTYK | c.1783A>G p.S595G | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV65685937; called by muse, mutect2, varscan2
- DYM | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV99493797; called by muse, varscan2
- ELK3 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 35/85 reads (41%) | catalogued as COSV99957749; called by muse, mutect2, varscan2
- ENPEP | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99487973; called by muse, mutect2, varscan2
- ERN2 | c.59T>C p.F20S | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99892081; called by muse, mutect2, varscan2
- EXOC3 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 138/220 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs779891627, COSV100155483; called by muse, mutect2, varscan2
- FAM193A | c.1124A>C p.E375A | Missense Mutation (SNP) | VAF 166/294 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100219481; called by muse, mutect2, varscan2
- FBXO43 | c.1190A>C p.E397A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV101413899; called by muse, mutect2, varscan2
- FZD10 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV57474698; called by muse, mutect2, varscan2
- HGF | c.1662C>A p.H554Q | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.105); catalogued as COSV55954859, COSV99737997; called by muse, mutect2, varscan2
- HNF4A | c.893-2A>T p.X298_splice | Splice Site (SNP) | VAF 43/117 reads (37%) | catalogued as COSV100291637; called by muse, mutect2, varscan2
- INTS1 | c.6277A>G p.S2093G | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV101248229; called by muse, mutect2, varscan2
- IRX1 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.024); catalogued as COSV100116677; called by muse, mutect2
- ITPRID1 | c.1124T>C p.L375S | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100087169; called by muse, varscan2
- LSG1 | c.1485A>T p.R495S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as COSV99503435; called by muse, mutect2, varscan2
- MACC1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV100256112; called by muse, mutect2, varscan2
- MAL | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.22); PolyPhen benign (0.218); catalogued as rs745452422, COSV100015848; called by muse, mutect2, varscan2
- MUC16 | c.27152C>A p.S9051Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV101200700; called by muse, mutect2, varscan2
- NFASC | c.3634T>C p.Y1212H (on ENST00000339876 / NM_001378329.1; = p.Y1141H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100365157; called by muse, mutect2, varscan2
- NUP133 | c.2433C>A p.C811* | Nonsense Mutation (SNP) | VAF 40/206 reads (19%) | catalogued as COSV99773287; called by muse, mutect2, varscan2
- OLFML3 | c.851G>T p.W284L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100233181; called by muse, mutect2
- PARD3 | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs780725925, COSV100401680; called by muse, mutect2, varscan2
- PLEKHM1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101378838; called by muse, mutect2, varscan2
- POLG2 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV99858174; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as COSV99461642; called by muse, mutect2, varscan2
- PPP1R9B | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.105); catalogued as COSV100380774; called by muse, mutect2, varscan2
- PPP6R1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV101337005; called by muse, mutect2, varscan2
- PRSS1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61196430; called by muse, mutect2, varscan2
- RELN | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100634468; called by muse, mutect2, varscan2
- TBC1D12 | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99831685; called by muse, mutect2, varscan2
- TMEM44 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/89 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs762425474, COSV99861937; called by muse, mutect2, varscan2
- TNFRSF10B | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as rs138183043; called by muse, mutect2, varscan2
- TRIO | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as COSV100710754; called by muse, mutect2, varscan2
- ZNF227 | c.1928A>T p.Q643L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100480547; called by muse, mutect2, varscan2
- ZNF493 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 75/247 reads (30%) | catalogued as rs1305249963, COSV100828823; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1240_1255del p.S414Pfs*5 | Frame Shift Del (DEL) | VAF 37/68 reads (54%) | called by mutect2, pindel, varscan2
- IGKV3-7 | c.206T>A p.I69N | Missense Mutation (SNP) | VAF 119/160 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- REPIN1 | c.502_506del p.H168Sfs*33 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- AKR1C3 | c.9C>T p.S3= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs1478371443, COSV101003146; called by muse, mutect2, varscan2
- ARHGEF11 | c.1968C>T p.T656= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs1307284762, COSV100168839; called by muse, mutect2, varscan2
- H4C7 | c.102T>C p.T34= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV99769197; called by muse, mutect2, varscan2
- KIFAP3 | c.639T>A p.L213= | Silent (SNP) | VAF 127/533 reads (24%) | catalogued as COSV100847085; called by muse, mutect2, varscan2
- MDC1 | c.4734T>C p.L1578= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs1347170945, COSV100903015; called by muse, varscan2
- MS4A6A | c.9A>G p.S3= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as COSV100124982; called by muse, mutect2, varscan2
- PCDHB5 | c.183T>A p.T61= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV99169336; called by muse, mutect2, varscan2
- TRPM5 | c.2292C>T p.P764= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV99330385; called by muse, mutect2, varscan2
- ZNF462 | c.5472G>A p.E1824= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs143553958; called by muse, mutect2, varscan2
- ARID5B | c.-1G>C | 5'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99690204; called by muse, mutect2, varscan2
